Somatic mutation profile of tumor specimen ALCH-B4XI-TTP1-A (aliquot ALCH-B4XI-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4XI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 33.0 years (12,046 days).
Specimen ALCH-B4XI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b2dcf99-af19-4cee-bb66-0146193048de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XI-NB1-A (Blood Derived Normal), aliquot ALCH-B4XI-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6f55d9d-c38b-47cb-be77-43ca79203b79

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'UTR 2, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP350 | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs899942622, COSV62602197, COSV62604502; called by muse, mutect2
- H3C10 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as rs767895248, COSV60797289, COSV60799089; called by muse, mutect2, varscan2
- ITPRID1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138066602; called by muse, mutect2, varscan2
- GGCT | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT10 | c.2356A>G p.T786A (on ENST00000307729 / NM_001195626.3; = p.T802A on NM_004641.3) | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKY | c.5_12del p.E2Gfs*93 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- UTRN | c.3282G>T p.W1094C | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2
- PADI2 | c.735C>T p.S245= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as rs201809367; called by muse, mutect2
- SPSB3 | c.249C>T p.S83= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- FAM20A | c.*2017G>T | 3'UTR (SNP) | VAF 82/775 reads (11%) | called by muse, varscan2
- FAM20A | c.*1953A>C | 3'UTR (SNP) | VAF 63/698 reads (9%) | called by muse, mutect2
- KIAA1522 | c.235+11990A>T | Intron (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- TMEM167B | c.-78G>C | 5'UTR (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
